Gene-level copy-number profile of tumor specimen TCGA-2J-AAB9-01A from TCGA case TCGA-2J-AAB9, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 71.0 years (25,920 days).
Specimen TCGA-2J-AAB9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.b5d2ea84-98c1-483a-bbb9-a945a4475121.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AAB9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccbc07f6-ee72-4ca4-8390-b0a418871e4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,694; copy number 2: 55,352; copy number 3: 597; copy number 4: 42; copy number 5: 33; copy number 6: 86; copy number 7: 3; copy number 10: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2J-AAB9-01A-11D-A40V-01): tumor purity 0.33, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 134 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:136,557,046–140,205,326, 63 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:151,054,897–151,621,193, 16 genes, copy number 6–10: AL133260.2, AL138733.1, AL133260.1, AL138733.2, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P.
- chr6:154,010,496–155,257,723, 19 genes, copy number 6 (within-gene range 1–6): OPRM1, IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8, AL591419.1, AL591499.1, SCAF8, RNU6-824P, TIAM2, AL121952.1, MIR1273C, U8, AL136228.1.
- chr8:12,945,642–16,000,324, 33 genes, copy number 5: TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1, AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2.
- chr10:85,599,552–86,366,795, 1 gene, copy number 7 (within-gene range 2–7): GRID1.
- chr10:86,052,448–86,264,788, 2 genes, copy number 7: RNA5SP322, MIR346.

Autosomal genes at a single copy (total copy number 1): 1,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
